Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2A1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2A1-06A (Metastatic).

DOB/Age/Sex.
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

History of melanoma left arm. Tumour left epitrochlear region. Histopathology.

MACROSCOPIC DESCRIPTION

(Dr /

"LESION LEFT ELBOW". An unorientated irregular piece of fatty tissue 40 x 20 x 18mm. The outer margin inked black. The cut surface shows an ill-defined nodule 11 x 9 x 8mm. One slice taken for tumour banking. Three slices of the entire nodule embedded in blocks A and B.

- A. Two slices.
- B. One slice.

MICROSCOPIC REPORT

Within a lymph node and extranodal tissue there is a spindle cell malignant neoplasm consistent with metastatic melanoma. There are foci of melanin pigment and acute haemorrhage and excision appears complete.

SUMMARY

Lymph node, left epitrochlear - Metastatic melanoma.

REPORTED BY: Prof.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, epitrochlear

c 77.3

hw 6/2/11

Primary Tumour Site Discrepancy		☒

A Unit of:

Pri

Source: NCI Genomic Data Commons file d0a59cf2-b853-44a9-b07c-81896312765f (TCGA-EE-A2A1.5F6CE73D-DD0C-4BB3-B572-4FABE2983B0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).